Somatic mutation profile of tumor specimen MMRF_2799_1_BM_CD138pos (aliquot MMRF_2799_1_BM_CD138pos_T1_KHS5U_L15739) from MMRF case MMRF_2799, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2799_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f34e029a-f694-4ca3-8279-a447ca1f2c96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2799_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2799_1_PB_WBC_C3_KHS5U_L15783; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5e6700c-acf0-46fa-801f-336732affa4b

The open-access MAF lists 94 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 26, Intron 12, Silent 9, 5'UTR 8, Frame Shift Del 2, 3'Flank 2, Splice Region 1, Splice Site 1, RNA 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP5 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs535257196; called by muse, mutect2, varscan2
- AFF2 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.061); catalogued as rs782692812; called by muse, mutect2, varscan2
- BTAF1 | c.5398C>G p.L1800V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as rs1243164968; called by muse, mutect2, varscan2
- CCDC105 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs565643585; called by muse, mutect2
- CEPT1 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs745978144; called by muse, mutect2, varscan2
- CHFR | c.872C>T p.A291V (on ENST00000432561 / NM_001161345.1; = p.A250V on NM_018223.2) | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1277312621, COSV99905178; called by muse, mutect2
- EPHB1 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV67655060, COSV67671851; called by muse, mutect2, varscan2
- IGHV2-70 | c.316A>T p.M106L | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.073); catalogued as rs373599438; called by muse, varscan2
- IGLV3-10 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 80/110 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs746915452; called by muse, varscan2
- PLCD4 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs758296014, COSV68842723; called by muse, mutect2, varscan2
- PTPN5 | c.1001-1G>T p.X334_splice | Splice Site (SNP) | VAF 17/140 reads (12%) | catalogued as COSV99061596; called by muse, mutect2, varscan2
- ROBO1 | c.3596G>A p.S1199N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as rs565000618; called by muse, mutect2
- SEZ6L2 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs375170414; called by muse, mutect2, varscan2
- ZNF578 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV69736969; called by muse, mutect2, varscan2
- ADGRL2 | c.2060C>A p.P687H (on ENST00000370717 / NM_001366005.1; = p.P674H on NM_012302.4) | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ANGEL1 | c.80G>A p.C27Y | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CCDC105 | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, varscan2
- DLGAP4 | c.1581T>G p.S527R | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- DNAH3 | c.7373T>C p.I2458T | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA8 | c.2380_2387del p.T794Gfs*104 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel
- HIVEP1 | c.2513G>T p.R838I | Missense Mutation (SNP) | VAF 141/321 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAK3 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 34/237 reads (14%) | called by muse, mutect2, varscan2
- JPH4 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- KLF10 | c.296_297del p.S99* | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- KRT6A | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 138/269 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- MAML3 | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- PCLO | c.11751G>T p.Q3917H | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PKP2 | c.650A>T p.Y217F | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLS1 | c.1108A>G p.N370D | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAB38 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2
- RPS21 | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 130/297 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC4A1AP | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SLC4A5 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- STARD7 | c.661-3del | Splice Region (DEL) | VAF 33/184 reads (18%) | called by mutect2, pindel, varscan2
- ZNF526 | c.1022T>G p.F341C | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- BABAM2 | c.939C>T p.D313= | Silent (SNP) | VAF 70/155 reads (45%) | catalogued as COSV59617520; called by muse, varscan2
- BEND4 | c.939G>A p.E313= | Silent (SNP) | VAF 5/105 reads (5%) | called by muse, mutect2
- C1orf216 | c.660A>T p.A220= | Silent (SNP) | VAF 70/134 reads (52%) | called by muse, mutect2, varscan2
- COPS8 | c.306C>T p.V102= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- ERP44 | c.51G>A p.L17= | Silent (SNP) | VAF 63/248 reads (25%) | called by muse, mutect2, varscan2
- GPR37 | c.1005G>A p.K335= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.90G>T p.L30= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as rs564942249; called by muse, mutect2, varscan2
- IGHV6-1 | c.279C>A p.I93= | Silent (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- SLC51A | c.417G>C p.G139= | Silent (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- ACBD5 | c.-43G>A | 5'UTR (SNP) | VAF 55/263 reads (21%) | called by muse, mutect2, varscan2
- AL583810.2 | n.329C>T | RNA (SNP) | VAF 142/328 reads (43%) | called by muse, mutect2, varscan2
- ANKS3 | c.170+63C>T | Intron (SNP) | VAF 17/67 reads (25%) | catalogued as rs893928668; called by muse, mutect2, varscan2
- C11orf87 | c.*4515G>C | 3'UTR (SNP) | VAF 21/167 reads (13%) | called by muse, mutect2, varscan2
- C8orf34 | c.327+168T>C | Intron (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- CACNA1B | c.-41C>T | 5'UTR (SNP) | VAF 13/24 reads (54%) | catalogued as rs918531150; called by muse, mutect2, varscan2
- CCDC171 | c.3600+112A>G | Intron (SNP) | VAF 61/207 reads (29%) | called by muse, mutect2, varscan2
- CDC37L1 | c.*126T>C | 3'UTR (SNP) | VAF 28/176 reads (16%) | called by muse, mutect2, varscan2
- CHST11 | c.*2995T>A | 3'UTR (SNP) | VAF 42/73 reads (58%) | called by muse, mutect2, varscan2
- CPPED1 | c.*226del | 3'UTR (DEL) | VAF 15/90 reads (17%) | catalogued as rs1349181399; called by mutect2, pindel, varscan2
- CSNK1G1 | c.*5967G>A | 3'UTR (SNP) | VAF 30/286 reads (10%) | called by muse, mutect2, varscan2
- CYP4F2 | c.919-63C>T | Intron (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- DDX49 | c.448-100A>C | Intron (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- DNAJB9 | c.*1019T>C | 3'UTR (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- E2F7 | c.*2118C>T | 3'UTR (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- F8 | c.-107T>G | 5'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- FNBP1L | c.*288G>A | 3'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- FRG2KP | chr16:31569119 G>A | 5'Flank (SNP) | VAF 22/85 reads (26%) | catalogued as rs1567414017; called by muse, mutect2, varscan2
- GOLGA7B | c.*1387dup | 3'UTR (INS) | VAF 12/130 reads (9%) | catalogued as rs1280165428; called by mutect2, pindel
- GRIN2A | c.*5005C>T | 3'UTR (SNP) | VAF 44/79 reads (56%) | called by muse, mutect2, varscan2
- HTR1A | c.-394G>T | 5'UTR (SNP) | VAF 69/108 reads (64%) | called by muse, mutect2, varscan2
- INKA2 | c.*3538G>A | 3'UTR (SNP) | VAF 14/53 reads (26%) | called by mutect2, varscan2
- KATNAL1 | c.*1783T>C | 3'UTR (SNP) | VAF 18/69 reads (26%) | catalogued as rs985854672; called by muse, mutect2, varscan2
- KIAA1958 | c.*3985G>A | 3'UTR (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- LACTB2 | c.286+443dup | Intron (INS) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- LARP1B | c.988+1342G>A | Intron (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- MAOB | c.*307C>A | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- MIB1 | c.*3345C>T | 3'UTR (SNP) | VAF 32/66 reads (48%) | catalogued as rs969730140; called by muse, varscan2
- NADSYN1 | c.1765-105_1765-104del | Intron (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- NHLRC3 | c.*531A>G | 3'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- NHLRC3 | c.*532A>G | 3'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1413+39G>T | Intron (SNP) | VAF 22/93 reads (24%) | catalogued as rs752640208; called by muse, mutect2, varscan2
- PAX8 | c.777+11G>T | Intron (SNP) | VAF 40/85 reads (47%) | called by muse, mutect2, varscan2
- PHEX | c.*651T>C | 3'UTR (SNP) | VAF 30/30 reads (100%) | called by muse, mutect2, varscan2
- RBM39 | c.-10T>A | 5'UTR (SNP) | VAF 156/348 reads (45%) | called by muse, mutect2
- SAMD4A | c.-248A>T | 5'UTR (SNP) | VAF 9/74 reads (12%) | catalogued as rs201002993, COSV51879974; called by muse, varscan2
- SKIDA1 | c.-268G>T | 5'UTR (SNP) | VAF 8/36 reads (22%) | catalogued as rs1431122129; called by muse, mutect2, varscan2
- SORBS1 | chr10:95312326 A>G | 3'Flank (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- SORD | c.*1146G>A | 3'UTR (SNP) | VAF 46/360 reads (13%) | called by muse, varscan2
- SPAG9 | c.*307G>C | 3'UTR (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- STAMBP | c.*2345C>T | 3'UTR (SNP) | VAF 36/215 reads (17%) | called by muse, mutect2, varscan2
- TBX2 | c.1052-201C>A | Intron (SNP) | VAF 56/232 reads (24%) | called by muse, mutect2, varscan2
- TMOD2 | c.*3645C>T | 3'UTR (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- TNFRSF1B | c.*200C>A | 3'UTR (SNP) | VAF 51/118 reads (43%) | called by muse, mutect2, varscan2
- TRIM16L | c.-28G>A | 5'UTR (SNP) | VAF 96/307 reads (31%) | catalogued as rs768397746, COSV67459494; called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28581037 G>A | 3'Flank (SNP) | VAF 54/122 reads (44%) | catalogued as rs562967053; called by muse, mutect2, varscan2
- UBOX5 | c.*1998C>T | 3'UTR (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2
- XYLB | c.*60C>G | 3'UTR (SNP) | VAF 101/251 reads (40%) | called by muse, mutect2, varscan2
- ZNF451 | c.186+9817A>G | Intron (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- ZNF660 | c.*985G>A | 3'UTR (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
